FM case AD15239 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/04539885-9ee2-4a17-8eae-09cc05637982

Female, 66.8 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
